Somatic mutation profile of tumor specimen C3L-04757-03 (aliquot CPT0255050006) from CPTAC case C3L-04757, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 68.1 years (24,886 days).
Specimen C3L-04757-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b25b030-5767-40ad-b64a-ee4afd941948.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04757-31 (Blood Derived Normal), aliquot CPT0255190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdf8242b-69fb-44a9-9f3d-0eb0d15ea144

The open-access MAF lists 1,136 somatic variants for this specimen: 769 protein-altering or splice-affecting, 214 silent, 153 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 670, Silent 214, Intron 78, Nonsense Mutation 47, RNA 26, Splice Site 21, 5'UTR 17, 3'UTR 14, Frame Shift Del 14, Splice Region 13, 5'Flank 12, 3'Flank 6.

Variants (750 of 1,136; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1906G>C p.G636R (on ENST00000288602 / NM_001374244.1; = p.G596R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs121913361, COSV56066561, COSV56185580, COSV56316158, COSV99954791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 33/159 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- A2ML1 | c.3698G>C p.G1233A | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1197246767, COSV100228565; called by muse, mutect2, varscan2
- AC068580.4 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 28/534 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); catalogued as rs943016868; called by muse, mutect2
- ACE | c.3137-1G>A p.X1046_splice | Splice Site (SNP) | VAF 121/459 reads (26%) | catalogued as COSV99327005; called by muse, mutect2, varscan2
- ACSM5 | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.367); catalogued as COSV100088736; called by muse, mutect2, varscan2
- ACTR10 | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs772399098, COSV54298488; called by muse, mutect2, varscan2
- ACTR8 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.354); catalogued as rs780432704; called by muse, mutect2
- ADAMTS18 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.557); catalogued as rs1239818884; called by muse, mutect2
- ADAMTS20 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs1270136784; called by muse, mutect2
- ADGRA1 | c.1341C>A p.S447R | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66927805; called by muse, mutect2, varscan2
- AIRE | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.538); catalogued as rs200359179; called by muse, mutect2
- ANGEL1 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 125/311 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs771796901, COSV51875519; called by muse, mutect2, varscan2
- ANXA13 | c.902C>G p.S301* | Nonsense Mutation (SNP) | VAF 7/118 reads (6%) | catalogued as COSV99146126; called by muse, mutect2
- APC2 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555101892; called by muse, mutect2
- APOH | c.974G>T p.C325F | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752860358; called by muse, mutect2, varscan2
- ARL15 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72292703; called by muse, mutect2, varscan2
- ARPP21 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV51792572; called by muse, mutect2
- ASPDH | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as rs1374328396, COSV99059342; called by muse, mutect2
- ATG9A | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 64/325 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100772579; called by muse, mutect2, varscan2
- ATP13A3 | c.3400C>G p.Q1134E | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99757514; called by muse, mutect2
- BCAR3 | c.1274C>G p.S425* | Nonsense Mutation (SNP) | VAF 45/282 reads (16%) | catalogued as COSV99550016; called by muse, mutect2, varscan2
- BCAS3 | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101175923; called by muse, mutect2, varscan2
- BDP1 | c.5453C>T p.S1818F | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.182); catalogued as rs780648683; called by muse, mutect2
- BNC2 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 32/390 reads (8%) | catalogued as COSV101031722; called by muse, mutect2
- BTN3A1 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV99176381; called by muse, mutect2, varscan2
- C12orf40 | c.979A>G p.M327V | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs768444507; called by muse, mutect2, varscan2
- C1orf167 | c.3982G>A p.D1328N | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.336); catalogued as rs760756415; called by muse, mutect2
- C2CD6 | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV53792789; called by muse, mutect2, varscan2
- C5orf47 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV60865138; called by muse, mutect2, varscan2
- C9 | c.879G>T p.M293I | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV54679055; called by muse, mutect2, varscan2
- CACNA1G | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1176922706; called by muse, mutect2, varscan2
- CARMIL1 | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100279039; called by muse, mutect2
- CCDC105 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs753393883, COSV99480142; called by muse, mutect2, varscan2
- CCDC168 | c.5408G>T p.R1803L | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV70556023; called by muse, mutect2, varscan2
- CCDC7 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV56537662; called by muse, mutect2
- CD3D | c.95G>C p.R32T | Missense Mutation (SNP) | VAF 17/501 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV52675608; called by muse, mutect2
- CD6 | c.1437C>A p.D479E | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as rs927945723; called by muse, mutect2, varscan2
- CDC25C | c.989G>T p.C330F | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767557314; called by muse, mutect2, varscan2
- CDC73 | c.1418-1G>A p.X473_splice | Splice Site (SNP) | VAF 25/250 reads (10%) | catalogued as COSV66467816; called by muse, mutect2
- CDH7 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59888680; called by muse, mutect2, varscan2
- CELF3 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs747941563, COSV99310428; called by muse, mutect2, varscan2
- CENPU | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.029); catalogued as rs917994568; called by muse, mutect2
- CFH | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100661615; called by muse, mutect2, varscan2
- CFHR5 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 57/233 reads (24%) | catalogued as rs142998381; called by muse, mutect2, varscan2
- CNGA4 | c.1153A>T p.M385L | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs762664483; called by muse, mutect2, varscan2
- COL3A1 | c.1409C>A p.P470H | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV58597545; called by muse, mutect2, varscan2
- COL6A5 | c.3705C>A p.S1235R | Missense Mutation (SNP) | VAF 82/419 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55197372; called by muse, mutect2, varscan2
- CPNE4 | c.508-1G>T p.X170_splice | Splice Site (SNP) | VAF 34/100 reads (34%) | catalogued as COSV101456773, COSV70195614; called by muse, mutect2, varscan2
- CPZ | c.1940G>T p.R647L (on ENST00000360986 / NM_001014447.3; = p.R636L on NM_003652.3) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755483835, COSV59922939; called by muse, varscan2
- CRACDL | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs768061978; called by muse, mutect2, varscan2
- CTAGE6 | c.1522G>C p.D508H | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs1458272023, COSV101417856; called by muse, mutect2, varscan2
- CTIF | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs1259990562; called by muse, mutect2, varscan2
- CWC27 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.328); catalogued as COSV66887027; called by muse, mutect2
- DAW1 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100006461; called by muse, mutect2, varscan2
- DCDC1 | c.5051C>A p.A1684D (on ENST00000597505 / NM_001367979.1; = p.A791D on NM_020869.3) | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1368389827; called by muse, mutect2
- DIDO1 | c.4831G>A p.E1611K | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs995950071; called by muse, mutect2, varscan2
- DLG2 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs868505277, COSV54627198; called by muse, mutect2
- DNER | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 46/371 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs755347007, COSV59162097; called by muse, mutect2, varscan2
- DOCK10 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV51361039; called by muse, mutect2
- DUS3L | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1467844481; called by muse, mutect2
- DUSP12 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.177); catalogued as COSV63411663; called by muse, mutect2
- EME2 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 41/431 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.117); catalogued as rs1207009155, COSV99170141; called by muse, mutect2
- EPB41L2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.146); catalogued as rs1331050549, COSV100440732; called by muse, mutect2
- EPB42 | c.1354G>C p.E452Q (on ENST00000441366 / NM_001114134.2; = p.E482Q on NM_000119.3) | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs774089462; called by muse, mutect2, varscan2
- EPHA3 | c.2134C>A p.R712S | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs777211567, COSV60693229, COSV60711436; called by muse, mutect2, varscan2
- EPHA7 | c.1084G>C p.D362H | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65182004; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1007G>C p.R336P | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV99212585; called by muse, mutect2
- ERG | c.202C>G p.P68A | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as COSV55733722, COSV55735789; called by muse, mutect2, varscan2
- EYS | c.6669G>T p.L2223F | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV65550603; called by muse, mutect2, varscan2
- EYS | c.91del p.E31Nfs*11 | Frame Shift Del (DEL) | VAF 40/271 reads (15%) | catalogued as COSV60990359; called by mutect2, pindel, varscan2
- F8 | c.1584C>G p.F528L | Missense Mutation (SNP) | VAF 25/480 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100811422; called by muse, mutect2
- FAM149B1 | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 38/224 reads (17%) | catalogued as rs1185348564; called by muse, mutect2, varscan2
- FAM170A | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as rs904773139, COSV58925726; called by muse, mutect2, varscan2
- FAM189B | c.1520G>T p.R507M | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs373745992; called by muse, mutect2, varscan2
- FAM47A | c.2149C>A p.P717T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60499194; called by muse, mutect2, varscan2
- FAM47A | c.2148C>A p.D716E | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs766975274; called by muse, mutect2, varscan2
- FAM47C | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1556333036, COSV63724946; called by muse, mutect2, varscan2
- FAM71A | c.1063G>T p.V355F | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.081); catalogued as COSV54234976; called by muse, mutect2, varscan2
- FAT4 | c.11410G>T p.D3804Y | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58709807; called by muse, mutect2, varscan2
- FBN2 | c.3200G>T p.G1067V | Missense Mutation (SNP) | VAF 69/467 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52505820; called by muse, mutect2, varscan2
- FHOD1 | c.374-1G>A p.X125_splice | Splice Site (SNP) | VAF 24/267 reads (9%) | catalogued as COSV99264296; called by muse, mutect2
- FLG | c.10351G>C p.E3451Q | Missense Mutation (SNP) | VAF 32/662 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.781); catalogued as COSV64252662; called by muse, mutect2
- FLG2 | c.2567C>A p.S856Y | Missense Mutation (SNP) | VAF 62/601 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV104428706; called by muse, varscan2
- FNTA | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs1485191311; called by muse, mutect2
- FREM3 | c.6055G>A p.E2019K | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.28); catalogued as COSV61682393; called by muse, varscan2
- FRK | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 44/294 reads (15%) | catalogued as rs753596132, COSV73384053; called by muse, mutect2, varscan2
- GAB1 | c.723A>G p.I241M | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs758565778; called by muse, mutect2, varscan2
- GEN1 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58055588; called by muse, mutect2
- GIPC3 | c.895C>T p.R299* (on ENST00000644946; = p.D294= on NM_133261.3) | Nonsense Mutation (SNP) | VAF 39/265 reads (15%) | catalogued as rs746316685; called by muse, mutect2, varscan2
- GMDS | c.740G>C p.R247P | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66417692; called by muse, mutect2
- GNAT2 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 68/483 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.396); catalogued as COSV63554601; called by muse, mutect2, varscan2
- GOLGA2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs1336351149, COSV70168916; called by muse, mutect2, varscan2
- GPBP1L1 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51972931; called by muse, mutect2, varscan2
- GPR78 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.182); catalogued as rs752766314, COSV66764111; called by muse, mutect2
- GPRC5B | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 109/341 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV56025854; called by muse, mutect2, varscan2
- HAVCR1 | c.473_486del p.M158Nfs*61 | Frame Shift Del (DEL) | VAF 68/437 reads (16%) | catalogued as rs386693994; called by mutect2, pindel*
- HCFC1 | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 13/421 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs1557114899, COSV100129357; called by muse, mutect2
- HCFC1 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 48/535 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV100128471; called by muse, mutect2
- HEATR9 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 33/484 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.434); catalogued as rs1247369293; called by muse, mutect2
- HEPHL1 | c.2364G>T p.R788S | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100244258; called by muse, mutect2, varscan2
- HOXA1 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58029792; called by muse, mutect2
- HOXB3 | c.732G>C p.K244N | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57486084; called by muse, mutect2
- HRNR | c.1313G>C p.S438T | Missense Mutation (SNP) | VAF 58/622 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs749602341, COSV64256667; called by muse, mutect2
- HSD3B2 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.166); catalogued as rs143169543; called by muse, mutect2
- HTR3C | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV59175853; called by muse, mutect2, varscan2
- HYDIN | c.14974G>T p.E4992* | Nonsense Mutation (SNP) | VAF 67/197 reads (34%) | catalogued as COSV66637761; called by muse, mutect2, varscan2
- IDO1 | c.555C>G p.F185L | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs376724401; called by muse, mutect2, varscan2
- IGKV4-1 | c.309C>G p.S103R | Missense Mutation (SNP) | VAF 93/328 reads (28%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.674); catalogued as rs372416266; called by muse, mutect2, varscan2
- IGKV6D-41 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 66/491 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs748762668; called by muse, mutect2, varscan2
- IGSF1 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV63838261; called by muse, mutect2, varscan2
- ILDR2 | c.1505G>T p.R502L | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs1195923323; called by muse, mutect2, varscan2
- ING5 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV57979780; called by muse, mutect2
- ISLR2 | c.1094C>G p.S365C | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV62301940; called by muse, mutect2
- ITGA10 | c.1507G>A p.V503I | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs372429851; called by muse, mutect2
- ITGB3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 93/717 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1215456865; called by muse, mutect2, varscan2
- JADE3 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV99510075; called by muse, mutect2
- JAM2 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.215); catalogued as rs1398152240, COSV57259391; called by muse, mutect2, varscan2
- JARID2 | c.3713C>A p.S1238* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as rs759455782, COSV100160735; called by muse, mutect2, varscan2
- JHY | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.058); catalogued as rs1404654902; called by muse, mutect2, varscan2
- KANK2 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV100763414; called by muse, mutect2
- KCNK2 | c.758C>A p.A253D (on ENST00000444842 / NM_001017425.3; = p.A238D on NM_014217.4) | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.195); catalogued as COSV67206733; called by muse, mutect2, varscan2
- KDM7A | c.1789C>G p.Q597E | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs778976493; called by muse, mutect2
- KIAA1210 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as rs750492632; called by muse, mutect2, varscan2
- KIF21B | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.337); catalogued as COSV59760944; called by muse, mutect2, varscan2
- KLC2 | c.1335C>T p.S445= | Splice Region (SNP) | VAF 14/67 reads (21%) | catalogued as rs923711661; called by muse, mutect2, varscan2
- KLHDC7B | c.1018G>A p.E340K (on ENST00000395676; = p.E981K on NM_138433.5) | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as rs773502147, COSV67464512, COSV67465067; called by muse, mutect2, varscan2
- KLHL11 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 30/253 reads (12%) | catalogued as COSV100044275, COSV59861724; called by muse, mutect2, varscan2
- KRT14 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 67/479 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs1427060922, COSV51421143, COSV51422262; called by muse, mutect2, varscan2
- KRTAP10-3 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV59966762; called by muse, mutect2, varscan2
- KRTAP19-3 | c.233C>A p.S78Y | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV100477473; called by muse, mutect2
- KRTAP4-6 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 122/890 reads (14%) | SIFT tolerated (0.09); catalogued as rs756146106; called by muse, varscan2
- KY | c.185G>C p.G62A | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV71016932; called by muse, mutect2
- LAMA2 | c.5122G>T p.E1708* | Nonsense Mutation (SNP) | VAF 24/236 reads (10%) | catalogued as COSV70354891; called by muse, mutect2, varscan2
- LAMA3 | c.5651A>T p.H1884L (on ENST00000313654 / NM_198129.4; = p.H275L on NM_000227.6) | Missense Mutation (SNP) | VAF 17/327 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs1471588614; called by muse, mutect2
- LAMB1 | c.4512C>G p.I1504M | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55968128; called by muse, mutect2
- LARP4 | c.433C>G p.Q145E | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762238929; called by muse, mutect2, varscan2
- LCT | c.2924G>T p.R975L | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV51549483; called by muse, mutect2, varscan2
- LINGO2 | c.941C>A p.P314H | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1254735053; called by muse, mutect2, varscan2
- LINGO2 | c.940C>A p.P314T | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as rs200998649; called by muse, mutect2, varscan2
- LMNB1 | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99745820; called by muse, mutect2, varscan2
- LPAR3 | c.40dup p.Y14Lfs*2 | Frame Shift Ins (INS) | VAF 12/88 reads (14%) | catalogued as rs767032705; called by mutect2, varscan2
- LRP2 | c.9837G>C p.W3279C | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55546021; called by muse, mutect2
- LRRIQ3 | c.1533G>T p.K511N | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100599558; called by muse, mutect2, varscan2
- MAGEA6 | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 31/365 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs146126949; called by muse, mutect2
- MAN2A1 | c.3233G>T p.R1078L | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.258); catalogued as rs554210296; called by muse, mutect2, varscan2
- MASP1 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV51458474; called by muse, mutect2
- MAST1 | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV52251312; called by muse, mutect2
- MATK | c.958G>T p.G320C (on ENST00000310132 / NM_139355.3; = p.G321C on NM_002378.4) | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV100035968; called by muse, mutect2, varscan2
- MAX | c.295+1G>T p.X99_splice | Splice Site (SNP) | VAF 314/739 reads (42%) | catalogued as CS115470, CS122951, COSV52417499, COSV52419813; called by muse, mutect2, varscan2
- MCCC2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); catalogued as rs370714351; called by muse, mutect2, varscan2
- MCM3AP | c.1121A>C p.H374P | Missense Mutation (SNP) | VAF 44/279 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs377692354; called by muse, mutect2, varscan2
- MERTK | c.2060G>T p.R687L | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54929415; called by muse, mutect2, varscan2
- MFN2 | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 85/569 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV52422373; called by muse, mutect2, varscan2
- MICAL2 | c.4633C>G p.P1545A | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as COSV56286404; called by muse, mutect2, varscan2
- MORC1 | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV51720984; called by muse, mutect2
- MTHFR | c.679A>T p.T227S | Missense Mutation (SNP) | VAF 101/404 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as CD155620; called by muse, mutect2, varscan2
- MUC16 | c.19966G>T p.A6656S | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV67469283; called by muse, mutect2, varscan2
- MUC3A | c.8966G>A p.G2989E | Missense Mutation (SNP) | VAF 47/368 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1359178061; called by muse, mutect2, varscan2
- MUC4 | c.6052C>T p.P2018S | Missense Mutation (SNP) | VAF 38/1410 reads (3%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.65); catalogued as rs758036933; called by muse, mutect2
- MYH4 | c.2012C>A p.P671H | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55116883; called by muse, mutect2, varscan2
- MYO16 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV51807053; called by muse, mutect2
- MYO1A | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 32/537 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV55656738; called by muse, mutect2
- NALCN | c.4654G>T p.E1552* | Nonsense Mutation (SNP) | VAF 77/229 reads (34%) | catalogued as COSV51945688; called by muse, mutect2, varscan2
- NAV3 | c.1436G>T p.C479F | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as rs1298332733; called by muse, mutect2, varscan2
- NFASC | c.263C>A p.P88H (on ENST00000339876 / NM_001378329.1; = p.P82H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV58360746; called by muse, mutect2, varscan2
- NOA1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1298640279; called by muse, mutect2
- NPHP3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.692); catalogued as rs1188632308, COSV58128975, COSV58129679; called by muse, mutect2, varscan2
- NPY5R | c.321G>C p.W107C | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58454131; called by muse, mutect2, varscan2
- NTNG1 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 77/236 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1165841994; called by muse, mutect2, varscan2
- NUAK2 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1286339754, COSV65682607; called by muse, mutect2, varscan2
- NUTM1 | c.3157C>A p.H1053N | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100148790; called by muse, mutect2, varscan2
- OR14I1 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.229); catalogued as COSV100700447; called by muse, mutect2, varscan2
- OR14K1 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV99315493; called by muse, mutect2, varscan2
- OR1L1 | c.985G>T p.V329L (on ENST00000373686; = p.V279L on NM_001005236.3) | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV58936609; called by muse, mutect2
- OR2AK2 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.127); catalogued as COSV63554575; called by muse, mutect2, varscan2
- OR2T11 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs1333534471; called by muse, mutect2, varscan2
- OR2T3 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100613181, COSV62082590; called by muse, mutect2, varscan2
- OR4A5 | c.445G>T p.G149* | Nonsense Mutation (SNP) | VAF 25/206 reads (12%) | catalogued as rs988516931, COSV60522253; called by muse, mutect2, varscan2
- OR4C16 | c.387C>G p.H129Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs150433977; called by muse, mutect2, varscan2
- OR4C6 | c.710C>G p.T237S | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); catalogued as COSV58604042; called by muse, mutect2, varscan2
- OR4N5 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61320601; called by muse, mutect2, varscan2
- OR6K6 | c.972G>A p.M324I (on ENST00000368144; = p.M300I on NM_001005184.1) | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV63744363; called by muse, mutect2
- OR8G5 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1328765458; called by muse, mutect2, varscan2
- OR9K2 | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.04); catalogued as COSV59531572; called by mutect2, varscan2
- OSBPL2 | c.1341-1G>T p.X447_splice (on ENST00000313733 / NM_144498.4; = p.X435_splice on NM_014835.4) | Splice Site (SNP) | VAF 27/138 reads (20%) | catalogued as COSV58220705; called by muse, mutect2, varscan2
- PAXX | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1229101410; called by muse, mutect2, varscan2
- PCDH15 | c.4540G>T p.D1514Y (on ENST00000644397 / NM_001354429.2; = p.K1474N on NM_001142770.3) | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV100905342; called by muse, mutect2, varscan2
- PCDH18 | c.1805G>C p.R602T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV61270550; called by muse, mutect2, varscan2
- PCDHA11 | c.71G>T p.W24L | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV56482856; called by muse, mutect2, varscan2
- PCDHB13 | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV53395014, COSV53397448; called by muse, mutect2
- PDE4DIP | c.3170C>T p.A1057V | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs150222697; called by muse, mutect2, varscan2
- PDZD2 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs967331354; called by muse, varscan2
- PDZD8 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV57827418; called by muse, mutect2
- PHF23 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 34/192 reads (18%) | catalogued as COSV99138345; called by muse, mutect2, varscan2
- PIK3AP1 | c.1800G>A p.M600I | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100225894; called by muse, mutect2
- PKD1 | c.11609G>A p.R3870H (on ENST00000262304 / NM_001009944.3; = p.R3869H on NM_000296.4) | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as CM1313904; called by muse, mutect2
- PLXNB2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs558651178, COSV63780233; called by muse, mutect2, varscan2
- PMM1 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99348237; called by muse, mutect2
- PNMA3 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs782057915, COSV64722119; called by muse, mutect2
- POM121L12 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1021830435, COSV68692627; called by muse, mutect2, varscan2
- PPP1R9A | c.2338G>C p.D780H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV99195921; called by muse, mutect2
- PPP3R2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140969417, COSV62451018, COSV62459717; called by muse, mutect2, varscan2
- PPP4R4 | c.459G>T p.W153C | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100175570; called by muse, mutect2, varscan2
- PRDM9 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 104/478 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs772688836; called by muse, mutect2, varscan2
- PROX1 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV99799751; called by muse, mutect2, varscan2
- PRR23C | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 130/503 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs760203167; called by muse, mutect2, varscan2
- PRSS1 | c.374C>A p.T125N | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV61193002; called by muse, mutect2, varscan2
- PRTG | c.2393A>T p.H798L | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs752607739; called by muse, mutect2, varscan2
- PSIP1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV101051048; called by muse, mutect2, varscan2
- PTPRN2 | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as rs1276612246; called by muse, mutect2, varscan2
- RELN | c.8236G>T p.D2746Y | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1303212382; called by muse, mutect2, varscan2
- RFX1 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99586375; called by muse, mutect2, varscan2
- RFX6 | c.639G>C p.L213F | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.172); catalogued as COSV100264280; called by muse, mutect2
- RGSL1 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54258682; called by muse, mutect2
- RIC8A | c.1204G>C p.E402Q (on ENST00000526104 / NM_001286134.1; = p.E408Q on NM_021932.5) | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57343991; called by muse, mutect2
- RNF31 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.76); catalogued as COSV53758458; called by muse, mutect2
- ROPN1 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV99481138; called by muse, mutect2, varscan2
- RPGR | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV58834834; called by muse, mutect2
- RPS6KA3 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65389004; called by muse, mutect2, varscan2
- RTN2 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.018); catalogued as rs1264052064; called by muse, mutect2
- RXFP1 | c.2077C>A p.H693N | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV57053426; called by muse, mutect2, varscan2
- RYR2 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1487120980, COSV100773288, COSV63711919; called by muse, varscan2
- SAMD3 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.027); catalogued as rs1218529024; called by muse, mutect2, varscan2
- SCN1A | c.2543G>T p.G848V (on ENST00000303395 / NM_001202435.3; = p.G837V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs1429732670, CD096208; called by muse, varscan2
- SDR39U1 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs1284785326, COSV52159844; called by muse, mutect2
- SEC14L5 | c.1511A>T p.Q504L | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV52037599; called by muse, mutect2, varscan2
- SEC16A | c.3731G>T p.S1244I | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); catalogued as rs1376119979; called by muse, mutect2, varscan2
- SETD5 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.32); catalogued as rs754641295; called by muse, mutect2
- SH3D19 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778769400, COSV58794081; called by muse, mutect2
- SI | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1437360669; called by muse, mutect2, varscan2
- SIGLEC6 | c.320G>A p.S107N | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.137); catalogued as COSV58431671; called by muse, mutect2, varscan2
- SIM2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51773531; called by muse, mutect2, varscan2
- SIRT1 | c.1411C>G p.H471D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53019294; called by muse, mutect2
- SLC24A2 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 58/428 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs1214067449; called by muse, mutect2, varscan2
- SLC35A4 | c.242del p.P81Hfs*23 | Frame Shift Del (DEL) | VAF 43/258 reads (17%) | catalogued as COSV60052095; called by mutect2, pindel, varscan2
- SLC36A3 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1424037195; called by muse, mutect2, varscan2
- SLC6A19 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 155/661 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs774192589; called by muse, mutect2, varscan2
- SLC7A13 | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV52533536; called by muse, mutect2
- SMC4 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61002757; called by muse, mutect2
- SOCS3 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58271147; called by muse, mutect2, varscan2
- SOGA1 | c.4547C>T p.T1516M | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.169); catalogued as rs762228809, COSV52931659; called by muse, mutect2, varscan2
- SORBS2 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs530628406; called by muse, mutect2, varscan2
- SPATA2L | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs139333873; called by muse, mutect2
- SPATA31A6 | c.3439C>A p.L1147M | Missense Mutation (SNP) | VAF 194/396 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.406); catalogued as COSV60535098; called by mutect2, varscan2
- SPRED2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 11/261 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV62693170; called by muse, mutect2
- STC2 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.167); catalogued as rs770708060, COSV54182271; called by muse, mutect2, varscan2
- STYXL2 | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747760393, COSV54801849; called by muse, mutect2, varscan2
- STYXL2 | c.2873C>A p.S958Y | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV54811600; called by muse, mutect2
- SYNE1 | c.17399C>T p.S5800F (on ENST00000367255 / NM_182961.4; = p.S5729F on NM_033071.3) | Missense Mutation (SNP) | VAF 28/447 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261541078; called by muse, mutect2
- TG | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.946); catalogued as COSV55076959; called by muse, mutect2, varscan2
- THBS2 | c.1916C>G p.A639G | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64677629; called by muse, mutect2, varscan2
- THOC6 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50188375; called by muse, mutect2
- TLN2 | c.5619G>T p.M1873I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs757391681; called by mutect2, varscan2
- TLR8 | c.2865C>A p.N955K (on ENST00000218032 / NM_138636.5; = p.N973K on NM_016610.4) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV54318162; called by muse, mutect2, varscan2
- TMEM41A | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56188638; called by muse, mutect2, varscan2
- TMPRSS11D | c.840C>A p.N280K | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.037); catalogued as rs377607444; called by muse, mutect2, varscan2
- TNR | c.2707G>A p.V903M | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV54877950, COSV99690971; called by muse, varscan2
- TPO | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 85/534 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs147325430, COSV61098181; called by muse, mutect2, varscan2
- TPX2 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772063777, COSV100302223; called by muse, mutect2, varscan2
- TRIM5 | c.1475G>C p.S492T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV59899541; called by muse, varscan2
- TRIM71 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs572598561, COSV101070368; called by muse, mutect2, varscan2
- TRIP12 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs777865514, COSV52261565; called by muse, mutect2, varscan2
- TRPV2 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs144086701; called by muse, mutect2, varscan2
- TTI1 | c.2101G>T p.G701W | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100989707; called by muse, mutect2, varscan2
- TTK | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1245281728, COSV57885919; called by muse, mutect2, varscan2
- TTN | c.54840C>A p.S18280R (on ENST00000591111; = p.S10856R on NM_003319.4) | Missense Mutation (SNP) | VAF 35/230 reads (15%) | PolyPhen benign (0.322); catalogued as COSV60235599; called by muse, mutect2, varscan2
- TUBA1C | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 65/447 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs377694330; called by muse, mutect2, varscan2
- UBASH3A | c.1823G>A p.G608E | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.735); catalogued as rs776857981; called by muse, mutect2, varscan2
- UBP1 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs749748973, COSV52145601; called by muse, mutect2, varscan2
- UBR1 | c.3496G>T p.V1166L | Missense Mutation (SNP) | VAF 56/428 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV51928348; called by muse, mutect2, varscan2
- USP40 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV52478767, COSV52479803; called by muse, mutect2
- VCAM1 | c.1381C>G p.L461V | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); catalogued as COSV99658665; called by muse, mutect2
- VN1R2 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | PolyPhen possibly damaging (0.893); catalogued as COSV59039104; called by muse, mutect2
- VPS41 | c.1309A>G p.K437E | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs752207580; called by muse, mutect2, varscan2
- VWA2 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs190448182, COSV53905245; called by muse, mutect2, varscan2
- WDFY4 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 60/430 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV57436479; called by muse, mutect2, varscan2
- WDR49 | c.539G>A p.G180E (on ENST00000308378 / NM_001366158.1; = p.G521E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57710579; called by muse, mutect2, varscan2
- WDR7 | c.2599A>G p.R867G | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1292821294; called by muse, mutect2, varscan2
- XIRP2 | c.7858G>C p.D2620H (on ENST00000628543; = p.D2795H on NM_152381.6) | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV99740792; called by muse, mutect2
- ZBBX | c.1034C>A p.P345Q | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV100283089; called by muse, mutect2, varscan2
- ZDHHC20 | c.972C>G p.I324M (on ENST00000400590 / NM_001330059.2; = p.I323M on NM_153251.3) | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.282); catalogued as COSV100203715; called by muse, mutect2, varscan2
- ZNF653 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 19/331 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV53402334, COSV99542308; called by muse, mutect2
- ZP3 | c.883G>A p.E295K (on ENST00000394857 / NM_001110354.2; = p.E244K on NM_007155.6) | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV60633025; called by muse, mutect2, varscan2
- ABCA9 | c.2648T>A p.L883Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ABCB4 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABL2 | c.870G>A p.M290I (on ENST00000502732 / NM_007314.4; = p.M275I on NM_005158.5) | Missense Mutation (SNP) | VAF 19/343 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- AC011455.2 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 53/476 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC104452.1 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 58/398 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTL6B | c.1063C>A p.Q355K | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACVR1C | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADAMTS15 | c.885del p.W295Cfs*5 | Frame Shift Del (DEL) | VAF 39/285 reads (14%) | called by mutect2, pindel, varscan2
- ADAMTS5 | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 28/423 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADARB2 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 90/179 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ADCY2 | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ADD2 | c.2078C>G p.S693C | Missense Mutation (SNP) | VAF 132/378 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ADGRA1 | c.1119C>A p.H373Q | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ADGRA3 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2
- ADGRG4 | c.7090C>A p.Q2364K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ADGRG5 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- ADGRL3 | c.4302G>T p.E1434D (on ENST00000506720 / NM_001322402.2; = p.E1323D on NM_015236.6) | Missense Mutation (SNP) | VAF 72/327 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ADGRL3 | c.4303G>T p.E1435* (on ENST00000506720 / NM_001322402.2; = p.E1324* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 69/323 reads (21%) | called by muse, mutect2, varscan2
- ADIPOR2 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADPGK | c.1370del p.E457Gfs*20 | Frame Shift Del (DEL) | VAF 49/303 reads (16%) | called by mutect2, pindel, varscan2
- AFF2 | c.1214G>T p.W405L | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- AFF2 | c.1215G>T p.W405C | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- AHDC1 | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.801); called by muse, mutect2
- ANK2 | c.11110G>C p.E3704Q | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ANKRD36 | c.2610G>C p.L870F | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD36C | c.1948C>G p.Q650E | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.028); called by muse, mutect2
- ANO5 | c.2062G>C p.A688P | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP4E1 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARAP3 | c.3925G>T p.D1309Y | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ARHGAP27 | c.1560G>C p.W520C (on ENST00000428638 / NM_001282290.1; = p.W179C on NM_199282.3) | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARMCX2 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARRDC2 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2
- ASPSCR1 | c.1404A>T p.A468= | Splice Region (SNP) | VAF 28/206 reads (14%) | called by muse, mutect2, varscan2
- ATG10 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- ATP13A3 | c.3013del p.A1005Pfs*53 | Frame Shift Del (DEL) | VAF 48/264 reads (18%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.2781G>C p.K927N | Missense Mutation (SNP) | VAF 25/515 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2
- ATP2C1 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP4B | c.391T>A p.C131S | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP6V0D2 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- ATP8B2 | c.538-2A>T p.X180_splice (on ENST00000672630; = p.X147_splice on NM_001005855.2) | Splice Site (SNP) | VAF 67/172 reads (39%) | called by muse, mutect2, varscan2
- AURKA | c.319+1G>T p.X107_splice | Splice Site (SNP) | VAF 47/291 reads (16%) | called by muse, mutect2, varscan2
- BBS7 | c.782G>C p.R261T | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BMP8B | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMS1 | c.3172G>A p.G1058S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- BRINP1 | c.794G>T p.C265F | Missense Mutation (SNP) | VAF 54/455 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- BTBD19 | c.203T>G p.V68G | Missense Mutation (SNP) | VAF 92/643 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C1QA | c.127G>C p.G43R | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf185 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by mutect2, varscan2
- C2CD4C | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C4orf47 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CAMSAP3 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CASS4 | c.1745C>A p.A582D | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CATSPERB | c.964A>G p.R322G | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CATSPERG | c.2974A>T p.K992* | Nonsense Mutation (SNP) | VAF 82/252 reads (33%) | called by muse, mutect2, varscan2
- CAVIN2 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2
- CBLN1 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2
- CCAR1 | c.2009T>A p.L670H | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CCDC102A | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC150 | c.2476G>C p.E826Q | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC168 | c.4657G>T p.G1553* | Nonsense Mutation (SNP) | VAF 55/221 reads (25%) | called by muse, mutect2, varscan2
- CCDC33 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCER1 | c.732G>T p.W244C | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CCL26 | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CD1D | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 25/170 reads (15%) | called by muse, mutect2, varscan2
- CD40 | c.81A>T p.R27S | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDH10 | c.2185C>A p.P729T | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH13 | c.413G>T p.R138M | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CDH20 | c.1113G>T p.Q371H | Missense Mutation (SNP) | VAF 140/415 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CDK5RAP3 | c.967G>T p.V323L | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CECR2 | c.2428G>A p.E810K (on ENST00000342247 / NM_001290047.2; = p.E627K on NM_001290046.1) | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.052); called by muse, mutect2
- CENPC | c.731A>T p.Q244L | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- CENPE | c.3531G>T p.M1177I | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPQ | c.523A>T p.N175Y | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CEP131 | c.2695G>A p.E899K (on ENST00000269392 / NM_001319228.2; = p.E896K on NM_014984.4) | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CERCAM | c.1695G>C p.W565C | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CFAP126 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- CFAP251 | c.3361G>C p.E1121Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2
- CFAP47 | c.8098C>A p.H2700N | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CGNL1 | c.1705G>C p.D569H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CHFR | c.948-2A>T p.X316_splice (on ENST00000432561 / NM_001161345.1; = p.X275_splice on NM_018223.2) | Splice Site (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- CHN1 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRNB2 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 60/558 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIC3 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLP1 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CLSTN2 | c.1979C>G p.P660R | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- COL12A1 | c.5072del p.P1691Lfs*12 | Frame Shift Del (DEL) | VAF 41/205 reads (20%) | called by mutect2, pindel, varscan2
- COL6A6 | c.5800G>C p.E1934Q | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.08); called by muse, mutect2
- COPB2 | c.2343T>A p.N781K | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CPNE8 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.603); called by muse, mutect2
- CPS1 | c.2829G>C p.Q943H | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CPSF6 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CRAT | c.1252G>T p.G418* | Nonsense Mutation (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- CREB3 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2
- CRMP1 | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 16/297 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- CRNN | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 90/239 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CRYBB2 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 32/441 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CSMD3 | c.8195T>C p.L2732P | Missense Mutation (SNP) | VAF 66/268 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CTSV | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.035); called by muse, mutect2
- CUBN | c.9721G>T p.V3241L | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.022); called by muse, mutect2
- CUL4B | c.89C>G p.S30* | Nonsense Mutation (SNP) | VAF 56/201 reads (28%) | called by muse, mutect2, varscan2
- CYP4F8 | c.542T>A p.L181Q | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- DBN1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- DCHS2 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- DCX | c.997C>G p.P333A (on ENST00000636035 / NM_001195553.2; = p.P328A on NM_000555.3) | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- DDX25 | c.509G>C p.C170S | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DENND4C | c.4737G>T p.L1579F (on ENST00000434457 / NM_001330640.2; = p.L1530F on NM_017925.7) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKI | c.3092C>A p.P1031H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- DHH | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- DISC1 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 78/435 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DLG1 | c.637-7C>T | Splice Region (SNP) | VAF 24/148 reads (16%) | called by muse, mutect2, varscan2
- DLG5 | c.5449C>T p.L1817F | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMBT1 | c.1834C>A p.Q612K | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DNAH11 | c.10189A>G p.I3397V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DNAH14 | c.1762G>T p.E588* (on ENST00000445597; = p.E569* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 67/233 reads (29%) | called by muse, mutect2, varscan2
- DNAJC9 | c.98G>C p.R33P | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNER | c.1636C>A p.P546T | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNM1 | c.1076del p.G359Efs*55 | Frame Shift Del (DEL) | VAF 29/210 reads (14%) | called by mutect2, pindel, varscan2
- DOCK10 | c.6218C>A p.P2073Q | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPM2 | c.3+5G>C | Splice Region (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- DRD5 | c.1120G>T p.G374W | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- DSEL | c.1914G>T p.W638C | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSTYK | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 94/332 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- DYSF | c.3098T>C p.M1033T | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EDIL3 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- EGFLAM | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF3G | c.36G>T p.W12C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- EIF3L | c.1575+3del | Splice Region (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- ELFN1 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ELFN2 | c.1930A>G p.S644G | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ELMO2 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EML1 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- ENPEP | c.2390A>C p.E797A | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by muse, mutect2
- EPHA8 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- EPHB2 | c.2386G>A p.E796K (on ENST00000400191 / NM_001309193.2; = p.E797K on NM_004442.7) | Missense Mutation (SNP) | VAF 61/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPPK1 | c.3953G>T p.G1318V | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ESPL1 | c.4663G>A p.D1555N | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ETS1 | c.482-1G>T p.X161_splice | Splice Site (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- EVC2 | c.519G>C p.L173= | Splice Region (SNP) | VAF 46/166 reads (28%) | called by muse, mutect2, varscan2
- EXOC6B | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.954); called by muse, mutect2
- EXOC8 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 71/542 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- EYS | c.7216C>A p.L2406I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- EYS | c.2569C>A p.H857N | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- FABP6 | c.70T>C p.S24P | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- FAM107B | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FAM47C | c.2486A>T p.Q829L | Missense Mutation (SNP) | VAF 114/215 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- FAT1 | c.8908G>C p.E2970Q | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.791); called by muse, mutect2
- FAT3 | c.2905G>T p.G969C | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT4 | c.4820G>T p.G1607V | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN2 | c.6793G>A p.A2265T | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FCGR1A | c.94A>T p.S32C | Missense Mutation (SNP) | VAF 167/576 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FCRLA | c.1072C>T p.L358F (on ENST00000367959; = p.L335F on NM_032738.4) | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FLG2 | c.5411G>A p.S1804N | Missense Mutation (SNP) | VAF 169/472 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FLG2 | c.4869G>C p.Q1623H | Missense Mutation (SNP) | VAF 22/375 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); called by muse, mutect2
- FLT1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMOD | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FOXD4L4 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 42/396 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by mutect2, varscan2
- FOXD4L4 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.889); called by mutect2, varscan2
- FOXD4L5 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by mutect2, varscan2
- FOXL1 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2
- FRAS1 | c.3561C>G p.L1187= | Splice Region (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2
- FREM3 | c.4308G>C p.L1436F | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2
- FSIP2 | c.7737G>A p.M2579I | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- GABPA | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.932); called by muse, mutect2
- GCSAM | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 26/522 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GDF2 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- GGA2 | c.690G>C p.K230N | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2
- GNS | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.348); called by muse, mutect2
- GPR182 | c.455A>T p.Y152F | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPR50 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- GRIK2 | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTPBP4 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- GUCY2F | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 69/161 reads (43%) | called by muse, mutect2, varscan2
- GUCY2F | c.1284G>T p.M428I | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCFC1 | c.548G>C p.G183A | Missense Mutation (SNP) | VAF 14/385 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2
- HECW1 | c.2591C>A p.A864D | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.171); called by muse, mutect2
- HHEX | c.503A>T p.K168M | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIP1 | c.1676C>A p.S559Y | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- HIVEP1 | c.6210-1G>C p.X2070_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- HIVEP1 | c.7796C>G p.S2599C | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- HMGB3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.087); called by muse, mutect2
- HOOK1 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- HPS4 | c.708A>T p.G236= | Splice Region (SNP) | VAF 45/273 reads (16%) | called by muse, mutect2, varscan2
- HPS5 | c.2983G>A p.E995K (on ENST00000349215 / NM_181507.2; = p.E881K on NM_007216.4) | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2
- HTR1A | c.523T>C p.W175R | Missense Mutation (SNP) | VAF 80/513 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HTR1F | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HTR7 | c.1355G>T p.W452L | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HYI | c.387-1G>T p.X129_splice (on ENST00000372434 / NM_001330526.2; = p.X104_splice on NM_031207.6) | Splice Site (SNP) | VAF 32/534 reads (6%) | called by muse, mutect2
- IFNAR2 | c.895A>T p.M299L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGF2R | c.6990G>C p.E2330D | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- IGHM | c.362A>T p.D121V | Missense Mutation (SNP) | VAF 166/354 reads (47%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- IGHMBP2 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- IGSF1 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IL1RAP | c.704-1G>T p.X235_splice | Splice Site (SNP) | VAF 51/262 reads (19%) | called by muse, mutect2, varscan2
- IL21R | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IL7R | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 18/351 reads (5%) | called by muse, mutect2
- INPP5B | c.1720G>T p.G574C (on ENST00000373023; = p.G494C on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IPO7 | c.779G>A p.C260Y | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQCD | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2
- IQGAP1 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 23/191 reads (12%) | called by muse, mutect2, varscan2
- IQGAP3 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); called by muse, mutect2
- IREB2 | c.701G>T p.W234L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.152); called by mutect2, varscan2
- IRX5 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA1 | c.2809G>T p.V937L | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNK17 | c.816G>T p.R272S | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNK3 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCTD8 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM5B | c.808+1G>T p.X270_splice | Splice Site (SNP) | VAF 17/172 reads (10%) | called by muse, mutect2, varscan2
- KIF11 | c.2689G>C p.E897Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KIF17 | c.1941C>A p.V647= | Splice Region (SNP) | VAF 56/463 reads (12%) | called by muse, mutect2, varscan2
- KIF26B | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.102); called by muse, mutect2
- KLC2 | c.1335-1G>C p.X445_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- KLF17 | c.852C>G p.C284W | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- KLHDC1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- KLHL20 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 27/494 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- KLRB1 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- KNG1 | c.1921G>T p.D641Y | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- KNTC1 | c.5208G>C p.L1736F | Missense Mutation (SNP) | VAF 78/328 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- KRT24 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KRT24 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- KRT73 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 46/361 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- L1CAM | c.1832G>T p.S611I | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- L1CAM | c.91+2T>C p.X31_splice | Splice Site (SNP) | VAF 52/525 reads (10%) | called by muse, mutect2, varscan2
- LAMA2 | c.1193T>C p.F398S | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- LAMA2 | c.3509G>T p.G1170V | Missense Mutation (SNP) | VAF 78/381 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- LAMA4 | c.4882A>T p.I1628F (on ENST00000230538 / NM_001105206.3; = p.I1621F on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- LARP1 | c.2052C>G p.F684L (on ENST00000518297 / NM_033551.3; = p.F607L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- LARP6 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCP2 | c.1518G>T p.R506S | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LIMA1 | c.1321C>T p.H441Y | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMBRD2 | c.1057C>G p.H353D | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.536); called by muse, mutect2
- LOX | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LOXHD1 | c.5350G>T p.G1784C (on ENST00000642948; = p.G1722C on NM_144612.7) | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPCAT1 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.152); called by muse, mutect2
- LPCAT1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2
- LRCH2 | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- LRPPRC | c.3587C>T p.A1196V | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- LRRC47 | c.1470G>T p.Q490H | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- LRRC66 | c.1574A>G p.Q525R | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LRRC8C | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 47/145 reads (32%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.1546G>C p.D516H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LY75 | c.3380C>T p.A1127V | Missense Mutation (SNP) | VAF 67/429 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYAR | c.1092G>C p.K364N | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.139); called by muse, mutect2
- MAB21L3 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 102/319 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEC1 | c.2080dup p.I694Nfs*7 | Frame Shift Ins (INS) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- MAGI2 | c.1293G>C p.K431N | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAPK1IP1L | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- MARCHF6 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- MBIP | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 25/377 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.244); called by muse, mutect2
- MCM10 | c.1541C>T p.S514F (on ENST00000484800 / NM_182751.3; = p.S513F on NM_018518.5) | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- MED10 | c.122+1G>T p.X41_splice | Splice Site (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- METTL18 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 13/251 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2
- MFAP1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 57/365 reads (16%) | called by muse, mutect2, varscan2
- MGAM2 | c.5421G>A p.W1807* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2
- MICA | c.959G>T p.C320F | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- MIPOL1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- MLLT10 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MORN4 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MRAP2 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MRM3 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPL50 | c.274del p.E92Kfs*5 | Frame Shift Del (DEL) | VAF 24/185 reads (13%) | called by pindel, varscan2
- MRPL50 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- MTAP | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated, low confidence (0.19); called by muse, mutect2, varscan2
- MUC17 | c.5348C>T p.S1783F | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2
- MUC22 | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.31); called by muse, mutect2, varscan2
- MYH8 | c.-30del | Splice Region (DEL) | VAF 75/297 reads (25%) | called by mutect2, pindel, varscan2
- MYO16 | c.2921G>C p.S974T | Missense Mutation (SNP) | VAF 64/371 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- MYO9A | c.1864C>G p.Q622E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.089); called by muse, mutect2
- NAA35 | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- NCAPG2 | c.2109C>G p.D703E | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NDUFS1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 41/226 reads (18%) | called by muse, mutect2, varscan2
- NEIL3 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.014); called by muse, mutect2
- NELL1 | c.2121C>A p.D707E | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- NFASC | c.262C>A p.P88T (on ENST00000339876 / NM_001378329.1; = p.P82T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/382 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- NIN | c.4078G>C p.D1360H | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2
- NIN | c.3892G>C p.E1298Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2
- NIPBL | c.3791A>T p.K1264I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NLRP10 | c.1327C>A p.L443I | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NPAS4 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPBWR1 | c.30G>T p.W10C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NPC1L1 | c.1686G>T p.K562N | Missense Mutation (SNP) | VAF 63/587 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by mutect2, varscan2
- NPR1 | c.2370G>C p.E790D | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2
- NPR1 | c.2421G>C p.E807D | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2
- NPY1R | c.288T>G p.F96L | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- NR1I3 | c.519C>G p.I173M | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NUP205 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUP210 | c.1311A>G p.I437M | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- NYNRIN | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCSTAMP | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- OIT3 | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10C1 | c.733C>A p.H245N (on ENST00000622521; = p.H243N on NM_013941.3) | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR10H5 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2L2 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- OR4A15 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- OR5AP2 | c.850T>C p.Y284H | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6J1 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- OR6P1 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 186/490 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OR6X1 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OR7D2 | c.904G>T p.G302W | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR8G1 | c.804G>T p.M268I | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- OS9 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OTOG | c.7349G>T p.W2450L | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); called by mutect2, varscan2
- OTOGL | c.1195T>G p.C399G (on ENST00000547103; = p.C390G on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTUD7B | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- P4HA1 | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PATZ1 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 28/322 reads (9%) | called by muse, mutect2
- PAXX | c.614G>C p.*205Sext*14 | Nonstop Mutation (SNP) | VAF 25/258 reads (10%) | called by muse, varscan2
- PCDH11X | c.60C>A p.H20Q | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH11X | c.2984del p.G995Afs*4 | Frame Shift Del (DEL) | VAF 150/374 reads (40%) | called by mutect2, pindel, varscan2
- PCDH15 | c.4933C>A p.P1645T | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT tolerated, low confidence (0.57); called by muse, mutect2, varscan2
- PCDHB2 | c.1247G>A p.R416K | Missense Mutation (SNP) | VAF 68/421 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCDHGA3 | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- PCDHGB6 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2
- PCMTD2 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDCD11 | c.3114G>T p.M1038I | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDE6B | c.609C>G p.S203R | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDLIM3 | c.584C>A p.P195H (on ENST00000284770 / NM_001257963.1; = p.P362H on NM_014476.6) | Missense Mutation (SNP) | VAF 81/558 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEX5L | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- PEX7 | c.920G>C p.W307S | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PGM2 | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PGM2 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PGR | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHLDB3 | c.1839C>G p.F613L | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- PIEZO2 | c.5466C>A p.D1822E | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PIP4P1 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 117/281 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PKD1 | c.11878G>A p.D3960N (on ENST00000262304 / NM_001009944.3; = p.D3959N on NM_000296.4) | Missense Mutation (SNP) | VAF 49/587 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- PKD1 | c.7148G>T p.R2383L | Missense Mutation (SNP) | VAF 168/410 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- PKP1 | c.382C>G p.R128G | Missense Mutation (SNP) | VAF 67/440 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PLA2G2A | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 36/608 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLA2G4A | c.267T>G p.I89M | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); called by muse, varscan2
- PLCB4 | c.605C>A p.T202K | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- PLEKHB2 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNB3 | c.4908G>C p.Q1636H | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.021); called by muse, mutect2
- PMPCA | c.437+2T>A p.X146_splice | Splice Site (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- PMVK | c.461C>G p.S154* | Nonsense Mutation (SNP) | VAF 18/303 reads (6%) | called by muse, mutect2
- PMVK | c.151T>A p.Y51N | Missense Mutation (SNP) | VAF 57/416 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLD1 | c.1498G>C p.G500R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- POM121 | c.1284G>C p.K428N (on ENST00000434423; = p.K163N on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/421 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PPP6R2 | c.2231C>T p.S744L (on ENST00000216061 / NM_001365836.1; = p.S717L on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- PRKCB | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRRG1 | c.467C>G p.S156* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- PSMA5 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PTGIS | c.1087G>C p.V363L | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRF | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.208); called by muse, mutect2
- PUDP | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2919A>T p.E973D | Missense Mutation (SNP) | VAF 94/394 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- RANBP2 | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RAP2B | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- RASA3 | c.449+1G>T p.X150_splice | Splice Site (SNP) | VAF 57/420 reads (14%) | called by muse, mutect2, varscan2
- RBM20 | c.3132G>T p.Q1044H | Missense Mutation (SNP) | VAF 64/412 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RBM25 | c.21G>C p.L7F | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.969); called by muse, mutect2
- RECK | c.2580G>C p.Q860H | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.259); called by muse, mutect2
- RELCH | c.2681-1G>T p.X894_splice | Splice Site (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2
- REM1 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 35/449 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2
- RGS21 | c.147G>C p.E49D | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RGS7BP | c.90C>A p.S30R | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- RILP | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- RNF216 | c.2282-1G>C p.X761_splice (on ENST00000425013 / NM_207116.3; = p.X818_splice on NM_207111.4) | Splice Site (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- RNF34 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 93/221 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNGTT | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPGR | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- RYR2 | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2
- RYR2 | c.3666C>A p.S1222R | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, varscan2
- RYR2 | c.3700G>C p.E1234Q | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, varscan2
- RYR3 | c.1572G>A p.L524= | Splice Region (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2
- S100A3 | c.123G>C p.E41D | Missense Mutation (SNP) | VAF 97/400 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SAMD9L | c.4050C>A p.N1350K | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SARM1 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SASS6 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- SAXO2 | c.1028G>C p.S343T | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SCAF11 | c.2389C>A p.P797T | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2
- SCGN | c.758G>C p.C253S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SCN10A | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- SCN7A | c.2060G>C p.G687A | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDR39U1 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 51/477 reads (11%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SEC63 | c.638del p.Y213Ffs*12 | Frame Shift Del (DEL) | VAF 53/377 reads (14%) | called by mutect2, pindel, varscan2
- SELPLG | c.745A>T p.T249S | Missense Mutation (SNP) | VAF 145/474 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SERPINI1 | c.1217A>G p.D406G | Missense Mutation (SNP) | VAF 77/303 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SETD9 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); called by muse, mutect2
- SEZ6L2 | c.815G>T p.R272L (on ENST00000308713 / NM_001114099.3; = p.R202L on NM_012410.4) | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- SFTPA1 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 50/662 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2
- SGK3 | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SHROOM2 | c.1171G>C p.A391P | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIN3B | c.739G>C p.G247R | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC12A5 | c.1907G>T p.C636F (on ENST00000454036 / NM_001134771.2; = p.C613F on NM_020708.5) | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- SLC12A8 | c.892G>T p.D298Y | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SLC25A5 | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- SLC2A6 | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- SLC35C2 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC39A12 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.031); called by muse, mutect2
- SLC4A10 | c.2737G>C p.G913R (on ENST00000446997 / NM_001354461.2; = p.G883R on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A10 | c.2738G>T p.G913V (on ENST00000446997 / NM_001354461.2; = p.G883V on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC66A2 | c.189G>C p.L63F | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A7 | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- SLTM | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SMAD6 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2
- SNCB | c.12C>A p.F4L | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATA31A6 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SPPL3 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5181C>A p.Y1727* | Nonsense Mutation (SNP) | VAF 65/201 reads (32%) | called by muse, mutect2, varscan2
- SRGAP2 | c.2431G>T p.V811L (on ENST00000624873 / NM_001170637.4; = p.V812L on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SRSF6 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- STAT6 | c.1089G>C p.L363= | Splice Region (SNP) | VAF 31/232 reads (13%) | called by muse, mutect2, varscan2
- STIL | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- STRADB | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2
- STYXL2 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- SULF2 | c.1749T>A p.S583R | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYNJ1 | c.4346C>G p.T1449S | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- SYNJ2 | c.2194G>C p.D732H | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYT12 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TAOK1 | c.11C>A p.T4N | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- TARS1 | c.700A>T p.K234* | Nonsense Mutation (SNP) | VAF 53/225 reads (24%) | called by muse, mutect2, varscan2
- TAS2R60 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- TBC1D19 | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.112); called by muse, mutect2
- TBC1D9 | c.210del p.D71Tfs*45 | Frame Shift Del (DEL) | VAF 18/172 reads (10%) | called by mutect2, varscan2
- TDRD15 | c.4119T>A p.F1373L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- TENT4A | c.2338A>T p.T780S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TEX33 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 27/218 reads (12%) | called by muse, mutect2, varscan2
- THBS3 | c.1943T>A p.L648Q | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.817); called by muse, mutect2
- THSD1 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLE4 | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLN1 | c.5806G>T p.A1936S | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- TMCO6 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 22/172 reads (13%) | called by muse, mutect2, varscan2
- TMEM63C | c.2038G>T p.G680C | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM67 | c.2203G>T p.V735L | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TMPRSS11D | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- TMTC4 | c.1186C>G p.L396V (on ENST00000376234 / NM_001350577.2; = p.L415V on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TNS1 | c.3166G>T p.G1056C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TP53BP1 | c.2255A>T p.E752V | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 98/187 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRIR | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.233); called by muse, mutect2
- TRO | c.2122G>C p.E708Q | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRPC1 | c.86A>T p.N29I | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- TRPC4AP | c.1121A>T p.Q374L | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TRPC6 | c.2284G>T p.V762L | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TSC22D1 | c.3019A>T p.K1007* (on ENST00000458659 / NM_183422.4; = p.K78* on NM_006022.4) | Nonsense Mutation (SNP) | VAF 34/134 reads (25%) | called by muse, mutect2, varscan2
- TTC14 | c.1943A>G p.E648G | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TTC28 | c.5062G>A p.E1688K | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); called by muse, mutect2
- TTN | c.23036C>A p.A7679D (on ENST00000591111; = p.A6752D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | PolyPhen benign (0.036); called by muse, mutect2
- TUBA1C | c.627C>G p.I209M | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXK | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TXNDC5 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, varscan2
- UBE2G2 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2
- UBE2O | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UBE2Q1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- UBR1 | c.4222G>T p.G1408C | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT2A3 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.302); called by muse, mutect2
- UMODL1 | c.3753G>A p.W1251* (on ENST00000408910 / NM_001004416.2; = p.W1379* on NM_173568.3) | Nonsense Mutation (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- UNC13A | c.2370C>A p.D790E | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UNC5A | c.2105G>T p.S702I | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- UNC80 | c.2541G>T p.R847S | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- UNC80 | c.3894C>A p.S1298R | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- UNC93A | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- UROC1 | c.1758G>T p.W586C | Missense Mutation (SNP) | VAF 142/629 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP11 | c.384C>G p.F128L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2
- VWA3B | c.3535G>T p.A1179S | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWA5B1 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, varscan2
- WASL | c.1252C>G p.Q418E | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2
- WBP4 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.112); called by muse, mutect2
- WDR17 | c.1690G>T p.G564W | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR17 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR3 | c.1238del p.G413Vfs*40 | Frame Shift Del (DEL) | VAF 50/267 reads (19%) | called by mutect2, pindel, varscan2
- WDTC1 | c.1969G>T p.G657W (on ENST00000319394 / NM_001276252.2; = p.G656W on NM_015023.5) | Missense Mutation (SNP) | VAF 90/300 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- YY2 | c.958A>G p.K320E | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZBED5 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.388); called by muse, mutect2
- ZBTB39 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 49/291 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZFP3 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
386 further variants in this file (19 protein-altering or splice-affecting, 214 silent, 153 other) are not listed here.
